Somatic mutation profile of tumor specimen TCGA-VS-A8QM-01A (aliquot TCGA-VS-A8QM-01A-11D-A37N-09) from TCGA case TCGA-VS-A8QM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: GX; Age at diagnosis: 47.0 years (17,168 days).
Specimen TCGA-VS-A8QM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06748674-defe-41ee-b9ca-5b7560f7e9c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8QM-10A (Blood Derived Normal), aliquot TCGA-VS-A8QM-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7d82154-1052-4731-b001-b9d1a3803c5e

The open-access MAF lists 111 somatic variants for this specimen: 75 protein-altering or splice-affecting, 30 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 30, Nonsense Mutation 4, Intron 3, Frame Shift Del 2, 3'Flank 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TGFBR2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893809, CM042122, CM064325, COSV55442890; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99710992; called by muse, mutect2, varscan2
- ABI3 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV99865751; called by muse, mutect2, varscan2
- ACP4 | c.408G>T p.W136C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1279892851, COSV99567825; called by muse, mutect2, varscan2
- ACSM5 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.302); catalogued as COSV100089325, COSV59370986; called by muse, mutect2, varscan2
- ADGRE2 | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV100216353; called by muse, mutect2, varscan2
- ADGRL2 | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54688710, COSV99591799; called by muse, mutect2, varscan2
- CCDC33 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs757090698, COSV58347636, COSV58348905; called by muse, mutect2, varscan2
- CERT1 | c.1840G>A p.D614N (on ENST00000405807 / NM_001130105.1; = p.D486N on NM_005713.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.479); catalogued as COSV99783584; called by muse, mutect2, varscan2
- CLCN5 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.118); catalogued as COSV101067278; called by muse, mutect2, varscan2
- CMIP | c.1984G>A p.G662R (on ENST00000537098 / NM_198390.2; = p.G568R on NM_030629.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101220952; called by muse, mutect2
- CT55 | c.450G>C p.L150F | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99358947; called by muse, mutect2
- CYLC1 | c.684G>C p.K228N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100255133, COSV100255375; called by mutect2, varscan2
- DHX36 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100273832; called by muse, mutect2, varscan2
- DIPK2A | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100237400; called by mutect2, varscan2
- EDEM2 | c.1416C>G p.I472M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as COSV63259496; called by muse, mutect2, varscan2
- EIF3A | c.2241G>C p.K747N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100974738; called by muse, mutect2
- EXOC7 | c.1136A>G p.Y379C (on ENST00000335146 / NM_001145297.4; = p.Y297C on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV100135580; called by muse, mutect2, varscan2
- FGR | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.129); catalogued as COSV100925879; called by muse, mutect2, varscan2
- FRMD3 | c.959C>G p.S320* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV58465154; called by muse, mutect2, varscan2
- GDA | c.384+1G>A p.X128_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as COSV99429633; called by muse, mutect2, varscan2
- GIPC1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs1194140215, COSV99466592; called by mutect2, varscan2
- GPAA1 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100284173; called by muse, mutect2, varscan2
- GPKOW | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs377169882, COSV99332769; called by muse, mutect2, varscan2
- GPR12 | c.794T>C p.M265T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.065); catalogued as COSV101198013; called by muse, mutect2, varscan2
- GPT | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as rs779578484, COSV99477522, COSV99477775; called by muse, mutect2, varscan2
- HLCS | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1275015391, COSV60797188; called by muse, mutect2, varscan2
- HMGN3 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as rs752710119, COSV51515411; called by muse, mutect2, varscan2
- HNRNPDL | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99787195; called by muse, mutect2
- IGSF8 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs376402367, COSV58759032; called by muse, mutect2, varscan2
- IQCH | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV100246239; called by muse, mutect2
- IQSEC2 | c.2138C>T p.S713F (on ENST00000642864 / NM_001111125.3; = p.S508F on NM_015075.2) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100945042; called by muse, mutect2, varscan2
- JAK2 | c.2359T>C p.C787R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101077833; called by mutect2, varscan2
- LRRCC1 | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100835546; called by muse, mutect2
- MAGEB2 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs368561784, COSV100975549; called by muse, mutect2, varscan2
- MPDZ | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100064026, COSV59938448; called by muse, mutect2, varscan2
- MPP1 | c.1198A>G p.I400V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs782396777, COSV101053993; called by muse, mutect2
- MYH4 | c.2507T>C p.L836P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1567701999, COSV99701386; called by muse, mutect2
- MYO5C | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766392804, COSV55911278; called by muse, mutect2, varscan2
- NFKBIL1 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as COSV101092952; called by muse, mutect2, varscan2
- OPA1 | c.1702G>A p.E568K (on ENST00000361510 / NM_130837.3; = p.E513K on NM_015560.3) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV100655426; called by muse, mutect2, varscan2
- OR5B21 | c.356A>G p.D119G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1033720708, COSV100835170; called by muse, mutect2, varscan2
- OXLD1 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV61303494; called by muse, mutect2
- PEG3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99689969; called by muse, mutect2
- PGAP6 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs764747772, COSV99170763; called by muse, mutect2, varscan2
- PKLR | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1485617455, COSV100712983; called by muse, mutect2, varscan2
- PPIG | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs1475681517, COSV99644813; called by muse, mutect2
- PRUNE2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100943229; called by muse, mutect2, varscan2
- PTPN21 | c.3008G>A p.G1003E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100162372; called by muse, mutect2, varscan2
- SETD4 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.283); catalogued as COSV59772340; called by muse, mutect2, varscan2
- SH3TC2 | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100102201; called by muse, mutect2, varscan2
- SKI | c.833C>G p.S278W | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101049530; called by muse, mutect2, varscan2
- SKIDA1 | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101481332; called by muse, mutect2
- SLC22A8 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100268027; called by muse, mutect2, varscan2
- SLC39A10 | c.1168A>G p.K390E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as COSV100660735; called by muse, mutect2
- SLC9A5 | c.2537C>G p.A846G | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1478030201, COSV100237527; called by muse, mutect2, varscan2
- SLIT3 | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs774734291, COSV100265764, COSV100268135; called by muse, mutect2, varscan2
- SMURF1 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100742556; called by muse, mutect2
- SOX6 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV100322907; called by muse, mutect2, varscan2
- SPEG | c.5683G>T p.E1895* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100405291; called by muse, mutect2
- STAMBPL1 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100904976, COSV64222503; called by muse, mutect2, varscan2
- STXBP5 | c.2749A>G p.I917V (on ENST00000321680 / NM_001127715.2; = p.I881V on NM_139244.4) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1469929715, COSV99470750; called by muse, mutect2, varscan2
- SUOX | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56267188, COSV99907172; called by muse, mutect2, varscan2
- TAMM41 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.91); catalogued as COSV99808912; called by muse, mutect2, varscan2
- TANC1 | c.4884G>C p.E1628D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as COSV99714844; called by muse, mutect2, varscan2
- TMC3 | c.2606G>A p.G869E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.231); catalogued as COSV100845977; called by muse, mutect2, varscan2
- TNFAIP8 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.652); catalogued as COSV99174274, COSV99174292; called by muse, mutect2, varscan2
- TULP1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV100004326; called by muse, mutect2, varscan2
- TULP4 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374889085; called by muse, mutect2, varscan2
- ZDBF2 | c.2399C>T p.S800L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV100985279; called by muse, mutect2, varscan2
- CA4 | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- IGHV3-53 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, mutect2
- MAP4K2 | c.1504del p.V502Wfs*2 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- RBM15 | c.404_405delinsT p.S135Lfs*38 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by pindel, varscan2*
- ADAM22 | c.774C>T p.S258= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs372427737; called by muse, mutect2, varscan2
- ADCY6 | c.1686G>A p.E562= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1259951770, COSV100326797; called by muse, mutect2, varscan2
- CEP131 | c.162G>A p.Q54= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- CPXM1 | c.1680C>T p.G560= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV101013806; called by muse, mutect2, varscan2
- CUEDC1 | c.780G>A p.E260= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100804803; called by muse, mutect2, varscan2
- ELP3 | c.1503G>A p.L501= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99834134; called by muse, mutect2, varscan2
- FRMD4A | c.2601C>T p.F867= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs1295307202, COSV100662286; called by muse, mutect2, varscan2
- GJB1 | c.735G>A p.Q245= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100661296; called by muse, mutect2
- GLIS2 | c.408C>T p.L136= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs773863545, COSV52111385; called by muse, mutect2, varscan2
- HRH3 | c.999G>A p.L333= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100420690; called by muse, mutect2, varscan2
- IK | c.846G>A p.L282= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV101341810; called by muse, mutect2, varscan2
- MAMDC2 | c.1590G>A p.R530= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV101014018; called by muse, mutect2, varscan2
- MAP3K15 | c.792G>T p.A264= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100135388, COSV58829814; called by muse, mutect2
- OR10A2 | c.696C>A p.L232= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100225145, COSV56300401; called by muse, mutect2, varscan2
- OR52N2 | c.153C>T p.I51= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100396200; called by muse, mutect2, varscan2
- PCDHA2 | c.2115C>T p.C705= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs781862610, COSV100974094; called by muse, mutect2, varscan2
- PIK3C2B | c.1134G>A p.L378= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100915075; called by muse, mutect2, varscan2
- RAD54L2 | c.357G>A p.E119= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99621667; called by muse, mutect2, varscan2
- RBM15 | c.357C>T p.S119= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs775493166, COSV100873488; called by muse, varscan2
- SLC9A5 | c.2250C>T p.I750= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100237525; called by muse, mutect2, varscan2
- SPTBN4 | c.996C>T p.I332= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV100151743; called by muse, mutect2
- STING1 | c.636G>C p.L212= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100423475; called by muse, mutect2, varscan2
- TGM6 | c.1653C>T p.H551= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs755072071, COSV99172218; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- THSD4 | c.2316C>T p.D772= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs763718096, COSV99966593; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.453C>T p.V151= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100552630; called by muse, mutect2, varscan2
- TTN | c.11836T>C p.L3946= (on ENST00000591111; = p.L3900= on NM_003319.4) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100624004; called by muse, mutect2, varscan2
- USP45 | c.1008A>G p.K336= | Silent (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- VWA3A | c.1461G>A p.R487= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100241179; called by muse, mutect2, varscan2
- WDR45 | c.201C>T p.G67= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as rs1557084463; called by muse, mutect2
- ZSCAN1 | c.1080C>T p.S360= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs144381428; called by muse, mutect2, varscan2
- ATRX | c.5566+114A>G | Intron (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- CST7 | c.-41G>A | 5'UTR (SNP) | VAF 14/101 reads (14%) | catalogued as COSV65195801; called by muse, mutect2, varscan2
- NDUFA5 | c.66+524C>G | Intron (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- TRAJ12 | chr14:22536175 G>C | 3'Flank (SNP) | VAF 10/102 reads (10%) | called by muse, varscan2
- TSPAN14 | chr10:80520740 C>T | 3'Flank (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99627905; called by muse, mutect2, varscan2
- TTN | c.10360+1229T>G | Intron (SNP) | VAF 7/62 reads (11%) | catalogued as rs369456547; called by muse, mutect2, varscan2
